Somatic mutation profile of tumor specimen MP2PRT-PARKTF-TMP1-A (aliquot MP2PRT-PARKTF-TMP1-A-1-0-D-A83C-36) from MP2PRT case MP2PRT-PARKTF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (857 days).
Specimen MP2PRT-PARKTF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c3b93b9-c100-46df-b105-2fde1791b5b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARKTF-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARKTF-NM1-A-1-0-D-A83C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0d84910-4b24-43cb-ace9-437925d5dcf9

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Frame Shift Ins 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLI1 | c.671_672dup p.E225Rfs*56 | Frame Shift Ins (INS) | VAF 70/290 reads (24%) | catalogued as rs1566559797; called by mutect2, varscan2
- ZSCAN5A | c.1264A>G p.T422A | Missense Mutation (SNP) | VAF 50/526 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- CCAR2 | c.2256C>T p.N752= | Silent (SNP) | VAF 82/366 reads (22%) | catalogued as rs765585516; called by muse, mutect2, varscan2
- COBLL1 | c.492A>C p.V164= (on ENST00000392717; = p.V126= on NM_014900.5) | Silent (SNP) | VAF 15/309 reads (5%) | called by muse, mutect2
- GALNTL6 | c.1356T>G p.P452= | Silent (SNP) | VAF 13/230 reads (6%) | called by muse, mutect2
